CCDI case PBCPYW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4cc8fb19-4d06-4702-8687-9aac2ad65129

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.8 years (2,121 days).

Biospecimens (3 samples)
- Sample 0DX5C8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX5CA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DX5CC: Tissue type: Tumor; Specimen type: Solid Tissue.
